Somatic mutation profile of tumor specimen ASCProject_0222_T2_WES (aliquot ASCProject_0222_T2_WES_1) from CMI case ASCProject_0222, project CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project. Sex at birth: male; Primary diagnosis: Angiosarcoma; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 74.4 years (27,174 days).
Specimen ASCProject_0222_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head, Face or Neck, NOS; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc9c675f-7a24-459d-95c6-5aedf671fb29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ASCProject_0222_SALIVA (Saliva), aliquot ASCProject_0222_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d3c1a5d-5e34-4a31-b71c-3e2710ff125d

The open-access MAF lists 1,742 somatic variants for this specimen: 1,030 protein-altering or splice-affecting, 466 silent, 246 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 935, Silent 466, Intron 116, Nonsense Mutation 46, RNA 46, 3'UTR 37, Splice Region 23, 5'UTR 21, 5'Flank 20, Splice Site 13, Frame Shift Del 9, 3'Flank 5.

Variants (750 of 1,742; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GALC | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs756352952, CM970560, COSV54327716; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PGR | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 24/132 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1000609240, COSV54795429; called by muse, mutect2, varscan2
- PROP1 | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 24/147 reads (16%) | catalogued as rs794726693; ClinVar: likely pathogenic; called by muse, varscan2
- RAF1 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 22/254 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs80338796, CM073301, COSV52574378, COSV52579821; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ABCA12 | c.7742G>A p.G2581D (on ENST00000272895 / NM_173076.3; = p.G2263D on NM_015657.3) | Missense Mutation (SNP) | VAF 63/315 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs138260707; called by muse, mutect2, varscan2
- ABCA13 | c.762C>T p.T254= | Splice Region (SNP) | VAF 36/119 reads (30%) | catalogued as rs761332043, COSV70047850; called by muse, mutect2, varscan2
- ABCA13 | c.5140G>A p.E1714K | Missense Mutation (SNP) | VAF 114/406 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.046); catalogued as COSV70027374, COSV70028617; called by muse, mutect2, varscan2
- ABCA2 | c.3337G>A p.E1113K (on ENST00000614293; = p.E1083K on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs367737102; called by muse, mutect2, varscan2
- ABCA6 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.859); catalogued as COSV52635745; called by muse, mutect2, varscan2
- ABCC3 | c.1400G>A p.G467E | Missense Mutation (SNP) | VAF 50/286 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV99558752; called by muse, mutect2, varscan2
- ABCC9 | c.3556C>T p.R1186W | Missense Mutation (SNP) | VAF 59/292 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886049169; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCG2 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs377457910; called by muse, mutect2, varscan2
- AC126283.2 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as CM161602, COSV67099310; called by muse, mutect2, varscan2
- ADAM19 | c.1701G>A p.M567I | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1351584458; called by muse, mutect2, varscan2
- ADAM7 | c.2197C>T p.H733Y | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs867658404, COSV51536214; called by muse, mutect2, varscan2
- ADAMTS13 | c.3424G>A p.E1142K | Missense Mutation (SNP) | VAF 72/327 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs587709422; called by muse, mutect2, varscan2
- ADAMTS3 | c.3413G>A p.G1138E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1346342321, COSV54392001; called by muse, mutect2, varscan2
- ADCY8 | c.1733G>A p.R578K | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as COSV53916718; called by muse, mutect2, varscan2
- ADGRA3 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV51566864; called by muse, mutect2, varscan2
- ADGRF1 | c.1833G>A p.W611* | Nonsense Mutation (SNP) | VAF 34/265 reads (13%) | catalogued as COSV51946394, COSV99347653; called by muse, mutect2, varscan2
- ADGRF2 | c.1991G>A p.G664E (on ENST00000296862 / NM_001368115.2; = p.G596E on NM_153839.7) | Missense Mutation (SNP) | VAF 35/240 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373612673, COSV99730614; called by muse, mutect2, varscan2
- ADGRG4 | c.3918A>C p.K1306N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV54950085; called by muse, mutect2, varscan2
- ADGRL3 | c.1481-1G>A p.X494_splice (on ENST00000506720 / NM_001322402.2; = p.X426_splice on NM_015236.6) | Splice Site (SNP) | VAF 16/108 reads (15%) | catalogued as COSV101547442, COSV104438828; called by muse, mutect2, varscan2
- ADGRV1 | c.1324C>T p.P442S | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.421); catalogued as COSV67995151; called by muse, mutect2, varscan2
- AFM | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.864); catalogued as rs1290800311; called by muse, mutect2
- AGO1 | c.1489G>A p.D497N | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.139); catalogued as COSV64595566, COSV64595982; called by muse, mutect2, varscan2
- AHNAK | c.14959C>T p.P4987S | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1314826313; called by muse, mutect2, varscan2
- AHNAK2 | c.14918C>T p.P4973L | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs968525356; called by muse, mutect2, varscan2
- AHNAK2 | c.14917C>T p.P4973S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV100318995; called by muse, mutect2, varscan2
- AL136295.1 | c.442C>T p.R148W | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.664); catalogued as rs758343224; called by muse, mutect2, varscan2
- ALK | c.3911G>A p.G1304E | Missense Mutation (SNP) | VAF 47/293 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1013688370, COSV66562966; called by muse, mutect2, varscan2
- AMY1B | c.879G>A p.K293= | Splice Region (SNP) | VAF 6/14 reads (43%) | catalogued as COSV100375574; called by mutect2, varscan2
- ANKS1B | c.956C>T p.T319I | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs1427784793; called by muse, mutect2, varscan2
- ANO4 | c.2143G>A p.E715K (on ENST00000392977 / NM_001286615.2; = p.E680K on NM_178826.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV100153723; called by muse, mutect2, varscan2
- AOX1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65980979; called by muse, mutect2, varscan2
- APBB1IP | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV100881955; called by muse, mutect2, varscan2
- APCS | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.166); catalogued as COSV54818025; called by muse, mutect2, varscan2
- APOB | c.7975C>T p.P2659S | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV51948312; called by muse, mutect2, varscan2
- APOBEC3D | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs368483208; called by muse, mutect2, varscan2
- APOE | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs142480126, CM1311778, COSV99376289; called by muse, mutect2, varscan2
- ARAP2 | c.3533G>A p.G1178E | Missense Mutation (SNP) | VAF 31/287 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV58287367; called by muse, mutect2, varscan2
- ARAP2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs199740529, COSV58285033; called by muse, mutect2
- ARHGAP44 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52399352; called by muse, mutect2, varscan2
- ARHGEF33 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 24/203 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs755156763; called by muse, mutect2, varscan2
- ARID5A | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs775122738; called by muse, mutect2, varscan2
- ASAH2 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61484419; called by muse, mutect2
- ASZ1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 89/375 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV52912224; called by muse, mutect2, varscan2
- ATRNL1 | c.3121C>T p.Q1041* | Nonsense Mutation (SNP) | VAF 9/61 reads (15%) | catalogued as COSV58094656; called by muse, mutect2, varscan2
- AXIN2 | c.2018C>T p.T673I | Missense Mutation (SNP) | VAF 43/150 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs576688801, COSV61058578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAG3 | c.1294G>A p.V432I | Missense Mutation (SNP) | VAF 100/437 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs1469879253; called by muse, mutect2, varscan2
- BDKRB2 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1258882849; called by muse, mutect2, varscan2
- BMP5 | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 18/388 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.011); catalogued as rs866784947, COSV63701354; called by muse, mutect2
- BOLL | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56575116; called by muse, varscan2
- BPIFB6 | c.1304A>G p.N435S | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.033); catalogued as COSV62756001; called by muse, varscan2
- BPIFC | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149939442; called by muse, mutect2, varscan2
- BRINP2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV64177086, COSV64178707; called by muse, mutect2, varscan2
- BRINP3 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV66534613, COSV99054926; called by muse, mutect2, varscan2
- C16orf96 | c.1501G>A p.D501N | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.096); catalogued as rs867339747; called by muse, varscan2
- C16orf96 | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV71471736; called by muse, varscan2
- C1orf87 | c.848G>A p.G283D | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1273908920; called by muse, mutect2, varscan2
- C2CD3 | c.1892C>T p.P631L | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs747053365; called by muse, mutect2, varscan2
- C2orf16 | c.4085A>G p.Q1362R | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs551442866; called by muse, mutect2, varscan2
- C3 | c.3976G>A p.E1326K | Missense Mutation (SNP) | VAF 51/304 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV55567907; called by muse, mutect2, varscan2
- C5 | c.2867G>A p.R956Q | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs751977981; called by muse, mutect2, varscan2
- C5orf24 | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 51/244 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1388464105; called by muse, mutect2, varscan2
- C6orf58 | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 43/257 reads (17%) | catalogued as COSV61666607; called by muse, mutect2, varscan2
- CABP1 | c.676G>A p.E226K (on ENST00000316803 / NM_001033677.1; = p.E23K on NM_004276.5) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99974910; called by muse, mutect2, varscan2
- CACNA1A | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM144895, COSV64204041; called by muse, mutect2, varscan2
- CACNA1I | c.4669G>A p.A1557T | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV100360750; called by muse, mutect2, varscan2
- CADPS | c.3235C>T p.R1079W | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.798); catalogued as COSV51873529; called by muse, mutect2, varscan2
- CALN1 | c.458T>A p.I153N (on ENST00000329008 / NM_001017440.3; = p.I195N on NM_031468.4) | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100204403; called by muse, mutect2, varscan2
- CAPN13 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs201525970, COSV54432486; called by muse, mutect2, varscan2
- CAPZA3 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as rs536940718, COSV56856950; called by muse, mutect2
- CARD10 | c.1535G>T p.S512I | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.347); catalogued as rs1451811162; called by muse, mutect2, varscan2
- CCDC178 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55788998; called by muse, mutect2, varscan2
- CCDC181 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.385); catalogued as rs781751281; called by muse, mutect2, varscan2
- CCDC60 | c.126G>A p.M42I | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs868528988; called by muse, mutect2, varscan2
- CCDC60 | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV59550968; called by muse, mutect2, varscan2
- CCDC73 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as rs867778040, COSV100067156; called by muse, mutect2, varscan2
- CCDC9 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1252145466; called by muse, mutect2, varscan2
- CCR3 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV62463541; called by muse, mutect2, varscan2
- CCT8L2 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs755392939; called by muse, mutect2
- CD302 | c.67G>A p.D23N | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.187); catalogued as COSV52032996; called by muse, mutect2, varscan2
- CD302 | c.66G>A p.A22= | Splice Region (SNP) | VAF 52/252 reads (21%) | catalogued as rs1323325211; called by muse, mutect2, varscan2
- CD3G | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758659595, COSV99416897; called by muse, mutect2, varscan2
- CDCP1 | c.2449del p.S817Afs*10 | Frame Shift Del (DEL) | VAF 24/120 reads (20%) | catalogued as COSV99943817, COSV99944449; called by mutect2, pindel, varscan2
- CDH6 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.851); catalogued as rs757553513; called by muse, mutect2, varscan2
- CDH9 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV50268721, COSV50334149; called by muse, mutect2, varscan2
- CDHR1 | c.1202G>A p.G401E | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as CM1312879; called by muse, mutect2
- CDK15 | c.886G>A p.G296S (on ENST00000652192 / NM_001366386.2; = p.G245S on NM_139158.2) | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53638345, COSV99643813; called by muse, mutect2, varscan2
- CDR1 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV65164124; called by muse, mutect2, varscan2
- CEACAM5 | c.1816C>T p.L606F | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.166); catalogued as COSV55750987; called by muse, mutect2, varscan2
- CELSR1 | c.3205G>A p.E1069K | Missense Mutation (SNP) | VAF 56/193 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); catalogued as rs1555941126; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CERS3 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.694); catalogued as COSV52568867; called by muse, mutect2, varscan2
- CFAP91 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 37/167 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs952201513; called by muse, mutect2, varscan2
- CFHR1 | c.617G>A p.G206E | Missense Mutation (SNP) | VAF 47/291 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV57626219; called by muse, mutect2, varscan2
- CFTR | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV50042515; called by muse, mutect2, varscan2
- CHD7 | c.4058C>T p.S1353F | Missense Mutation (SNP) | VAF 65/268 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV71113405; called by muse, mutect2, varscan2
- CHD9 | c.7408C>T p.P2470S (on ENST00000398510 / NM_001382353.1; = p.P2454S on NM_025134.7) | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.365); catalogued as rs748858977; called by muse, mutect2, varscan2
- CHIA | c.659G>A p.G220D (on ENST00000343320; = p.G112D on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as COSV58479098; called by muse, mutect2, varscan2
- CHP2 | c.540C>T p.S180= | Splice Region (SNP) | VAF 22/118 reads (19%) | catalogued as COSV55650285, COSV55650742, COSV55650987; called by muse, mutect2, varscan2
- CLEC4G | c.855G>A p.W285* | Nonsense Mutation (SNP) | VAF 24/133 reads (18%) | catalogued as rs1015328836, COSV61003610; called by muse, mutect2, varscan2
- CLTCL1 | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1555955401, COSV54234381; called by muse, mutect2, varscan2
- CMYA5 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 33/177 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101483724; called by muse, mutect2, varscan2
- CMYA5 | c.4735G>A p.G1579S | Missense Mutation (SNP) | VAF 41/198 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV71406136; called by muse, mutect2, varscan2
- CNKSR2 | c.2605G>A p.D869N | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV54256693, COSV99667157; called by muse, mutect2, varscan2
- CNR1 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 42/213 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.444); catalogued as rs771535671; called by muse, varscan2
- CNTN4 | c.1781G>A p.R594K | Missense Mutation (SNP) | VAF 69/226 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.085); catalogued as COSV61881652; called by muse, mutect2, varscan2
- CNTN5 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs866845091, COSV54279011; called by muse, mutect2
- CNTN6 | c.2342A>T p.Y781F | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs773287290; called by muse, mutect2, varscan2
- CNTNAP2 | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 57/308 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62170695; called by muse, mutect2, varscan2
- CNTNAP2 | c.1084-1G>A p.X362_splice | Splice Site (SNP) | VAF 43/276 reads (16%) | catalogued as COSV62189256; called by muse, mutect2, varscan2
- CNTNAP2 | c.2576C>T p.S859L | Missense Mutation (SNP) | VAF 98/403 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs866153908, COSV62154032; called by muse, mutect2, varscan2
- CNTNAP5 | c.2534C>T p.P845L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as COSV101444153; called by muse, mutect2, varscan2
- COL11A1 | c.4779G>A p.M1593I | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as COSV62175697, COSV62177733; called by muse, mutect2, varscan2
- COL13A1 | c.623G>A p.G208E (on ENST00000398978 / NM_001130103.2; = p.G170E on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100637627, COSV62569001; called by muse, mutect2, varscan2
- COL15A1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs1365089789, COSV100897686; called by muse, mutect2, varscan2
- COL15A1 | c.2861G>A p.G954E | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757069097, COSV66646907; called by muse, mutect2, varscan2
- COL18A1 | c.4657C>T p.P1553S (on ENST00000359759 / NM_130444.3; = p.P1318S on NM_030582.4) | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.934); catalogued as rs780206261; called by muse, mutect2, varscan2
- COL18A1 | c.4658C>T p.P1553L (on ENST00000359759 / NM_130444.3; = p.P1318L on NM_030582.4) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as rs749512380, COSV60587193; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A1 | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 129/332 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65428706; called by muse, mutect2, varscan2
- COL4A4 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 30/155 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs572923977, COSV61630879; called by muse, mutect2, varscan2
- COL4A4 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758729139, CM161103, COSV61629447, COSV61632533; called by muse, mutect2, varscan2
- COL6A3 | c.3464T>G p.V1155G | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV55082033; called by muse, mutect2, varscan2
- COL9A2 | c.428G>A p.G143E | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756445062, COSV101025729; called by muse, mutect2, varscan2
- CPNE4 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); catalogued as COSV70198839; called by muse, varscan2
- CPS1 | c.3743G>A p.G1248E | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.669); catalogued as rs1243506295, COSV51810934; called by muse, mutect2, varscan2
- CPS1 | c.4468C>T p.H1490Y | Missense Mutation (SNP) | VAF 56/296 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.67); catalogued as rs1393116118, COSV51818404; called by muse, mutect2, varscan2
- CRACD | c.2518G>A p.E840K | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99949213; called by muse, mutect2, varscan2
- CRYL1 | c.623G>A p.R208Q | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs747838743; called by muse, mutect2, varscan2
- CSMD3 | c.1684C>T p.P562S (on ENST00000297405 / NM_001363185.1; = p.P458S on NM_052900.3) | Missense Mutation (SNP) | VAF 79/282 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs1418135224; called by muse, mutect2, varscan2
- CST8 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55671186; called by muse, mutect2, varscan2
- CYB5D2 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 96/498 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs141654519; called by muse, mutect2, varscan2
- CYP11A1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV51430965; called by muse, mutect2, varscan2
- CYP2C8 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64877083; called by muse, varscan2
- CYP2C8 | c.91C>T p.P31S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs944376559; called by muse, mutect2, varscan2
- CYP4A11 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs750399611, COSV60222706; called by muse, mutect2, varscan2
- CYP7A1 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56966275; called by muse, mutect2, varscan2
- DCC | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV59101712; called by muse, mutect2, varscan2
- DCN | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 49/338 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV50007289; called by muse, mutect2, varscan2
- DDX60 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767373127, COSV67095656; called by muse, mutect2, varscan2
- DEFB131A | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.931); catalogued as COSV58416226; called by muse, mutect2, varscan2
- DEPTOR | c.372C>A p.F124L | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as COSV53815671; called by muse, mutect2, varscan2
- DGKI | c.2167C>T p.R723C | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs760167594, COSV55937658; called by muse, varscan2
- DGKQ | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.45); catalogued as rs749185097; called by muse, mutect2, varscan2
- DIDO1 | c.3677C>T p.P1226L | Missense Mutation (SNP) | VAF 80/325 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs771349573, COSV56619411; called by muse, mutect2, varscan2
- DISP1 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs774186525; called by muse, mutect2
- DLGAP3 | c.937C>T p.L313F | Missense Mutation (SNP) | VAF 63/178 reads (35%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.737); catalogued as rs766919404, COSV99332123; called by muse, mutect2, varscan2
- DNAH7 | c.10807C>T p.P3603S | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56766285; called by muse, mutect2, varscan2
- DNAH9 | c.2275C>T p.P759S | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV52359825; called by muse, mutect2, varscan2
- DNAH9 | c.9579G>A p.M3193I | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1177230757; called by muse, mutect2, varscan2
- DNAJC10 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193887988; called by muse, mutect2, varscan2
- DNPEP | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 48/273 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1182494773, COSV56110187; called by muse, mutect2, varscan2
- DPEP2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs1248948278; called by muse, mutect2, varscan2
- DSC1 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs267605150, COSV99937667; called by muse, mutect2, varscan2
- DSC3 | c.2477A>C p.Q826P | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV64575144; called by muse, mutect2, varscan2
- DSCAM | c.5498C>T p.T1833I | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV101260107; called by muse, mutect2, varscan2
- DSG4 | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 21/173 reads (12%) | catalogued as rs1384407099, COSV57390566; called by muse, mutect2, varscan2
- DSP | c.8472_8483del p.S2843_R2846del | In Frame Del (DEL) | VAF 12/65 reads (18%) | catalogued as rs397516967; ClinVar: uncertain significance / likely benign; called by mutect2, pindel, varscan2
- DUSP4 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.293); catalogued as rs772256235, COSV53545403; called by muse, mutect2, varscan2
- EIF2AK4 | c.2491G>A p.E831K | Missense Mutation (SNP) | VAF 74/342 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375456378; called by muse, mutect2, varscan2
- ELAC2 | c.1691G>A p.R564H | Missense Mutation (SNP) | VAF 153/575 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.141); catalogued as rs1346085881; called by muse, mutect2, varscan2
- ELMO1 | c.1867C>T p.P623S | Missense Mutation (SNP) | VAF 71/364 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV99049559; called by muse, mutect2, varscan2
- EPO | c.442C>T p.P148S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.087); catalogued as rs1426639177; called by muse, mutect2, varscan2
- ERMN | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as rs756451218; called by muse, mutect2, varscan2
- F2R | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 49/283 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100058727; called by muse, mutect2, varscan2
- FAAH | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 147/571 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99680381; called by muse, mutect2, varscan2
- FAM184B | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.986); catalogued as COSV53955952; called by muse, mutect2, varscan2
- FAM186A | c.3619C>T p.L1207F | Missense Mutation (SNP) | VAF 36/180 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); catalogued as rs1316137790; called by muse, varscan2
- FAM234B | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 81/371 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV99545277; called by muse, mutect2, varscan2
- FAM83B | c.2033G>A p.G678E | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV60919550; called by muse, mutect2
- FAN1 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 94/342 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1045312673; called by muse, mutect2, varscan2
- FAT1 | c.6460G>A p.V2154M | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV71675490; called by muse, mutect2, varscan2
- FBN3 | c.5813G>A p.G1938E | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV54458034; called by muse, mutect2, varscan2
- FCRL1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.343); catalogued as rs750060612, COSV63826711, COSV63828322; called by muse, varscan2
- FCRL5 | c.223C>T p.L75F | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.093); catalogued as COSV62517425, COSV62517985; called by muse, varscan2
- FER1L5 | c.2551G>A p.E851K (on ENST00000623019; = p.E856K on NM_001293083.2) | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1231880964; called by muse, mutect2, varscan2
- FERMT3 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 73/360 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as rs140992702; called by muse, mutect2, varscan2
- FMO3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 39/244 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs774866097, CM078327; called by muse, mutect2, varscan2
- FNDC1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs1364001630, COSV51936655, COSV51939017; called by muse, mutect2, varscan2
- FNDC7 | c.769C>T p.Q257* | Nonsense Mutation (SNP) | VAF 30/142 reads (21%) | catalogued as rs1422212806; called by muse, mutect2, varscan2
- FOXL3 | c.304G>A p.G102S | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567901079; called by muse, mutect2, varscan2
- FRAS1 | c.5659G>A p.G1887R | Missense Mutation (SNP) | VAF 35/186 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.009); catalogued as rs1283518456; called by muse, mutect2, varscan2
- FREM2 | c.8375C>T p.P2792L | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54847848; called by muse, mutect2, varscan2
- FSCB | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as COSV61218991; called by muse, mutect2, varscan2
- FSIP2 | c.6061G>A p.E2021K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV58090339; called by muse, mutect2, varscan2
- FSTL5 | c.2334G>A p.M778I | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV60209996; called by muse, mutect2, varscan2
- FUCA1 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 144/390 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.323); catalogued as rs766121368; called by muse, mutect2, varscan2
- GABRA2 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.014); catalogued as COSV62912927; called by muse, mutect2
- GABRA6 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs766046638, COSV50880397; called by muse, mutect2, varscan2
- GALNT17 | c.289G>A p.G97R | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61167028; called by muse, mutect2, varscan2
- GALNT5 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52036370; called by muse, varscan2
- GCKR | c.1525C>T p.R509W | Missense Mutation (SNP) | VAF 38/186 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs150882877; called by muse, mutect2, varscan2
- GCSAML | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100825879, COSV63579149; called by muse, varscan2
- GFI1B | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs749864797, COSV59744833; called by muse, mutect2, varscan2
- GLI3 | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 62/378 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs1156987879, COSV67895267; called by muse, mutect2, varscan2
- GLRA3 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.919); catalogued as COSV99926893; called by muse, mutect2, varscan2
- GLRB | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs149915285; called by muse, mutect2, varscan2
- GNB5 | c.257G>A p.R86Q (on ENST00000261837 / NM_016194.4; = p.R44Q on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs776406670, COSV55900685; called by muse, mutect2, varscan2
- GNPAT | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 188/599 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as COSV100791679; called by muse, mutect2, varscan2
- GPC4 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs778935883; called by muse, mutect2, varscan2
- GPR158 | c.3522G>A p.W1174* | Nonsense Mutation (SNP) | VAF 55/202 reads (27%) | catalogued as rs1382007197; called by muse, mutect2, varscan2
- GPR158 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 56/202 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV66283134; called by muse, mutect2, varscan2
- GREB1L | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs748956908; called by muse, mutect2, varscan2
- GRID1 | c.428C>T p.S143L | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs777966375, COSV100027166; called by muse, mutect2, varscan2
- GRID2 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56186431; called by muse, mutect2, varscan2
- GRXCR2 | c.59G>A p.R20Q | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1264319289, COSV65061327; called by muse, varscan2
- GSDME | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 188/661 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs981315836; called by muse, mutect2, varscan2
- GTF2IRD1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1291434200; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2765C>T p.S922F (on ENST00000265755 / NM_016328.3; = p.S907F on NM_005685.4) | Missense Mutation (SNP) | VAF 105/364 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as COSV56090769; called by muse, mutect2, varscan2
- GUCY1B1 | c.1670G>A p.G557E | Missense Mutation (SNP) | VAF 64/279 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1371753022; called by muse, mutect2, varscan2
- GUCY2D | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 62/379 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342592717; called by muse, mutect2, varscan2
- HBG2 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 65/319 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs63751148, CM0910355, COSV57964828; ClinVar: other; called by muse, mutect2, varscan2
- HCN1 | c.2527C>T p.R843* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as rs1046832984, COSV57504666, COSV57542388; called by muse, mutect2
- HCRTR2 | c.454C>T p.R152W | Missense Mutation (SNP) | VAF 73/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866684522, COSV63795299; called by muse, mutect2, varscan2
- HDAC3 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 98/382 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747678007, COSV59496962; called by muse, mutect2, varscan2
- HECW1 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 88/408 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.054); catalogued as rs780933393; called by muse, mutect2, varscan2
- HIF3A | c.1690C>T p.P564S (on ENST00000377670 / NM_152795.4; = p.P495S on NM_022462.4) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV52199654; called by muse, mutect2, varscan2
- HMGCS2 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749637124, COSV65567331; called by muse, mutect2, varscan2
- HOXD12 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1373817873; called by muse, mutect2, varscan2
- HSD3B1 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV52489553; called by muse, mutect2, varscan2
- HTR3A | c.1049G>A p.R350K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs867161218, COSV100248571; called by muse, mutect2, varscan2
- HTT | c.5792C>T p.S1931F | Missense Mutation (SNP) | VAF 91/463 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV61857160; called by muse, mutect2, varscan2
- IFNA17 | c.464C>A p.T155K | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs544183292, COSV69738070; called by muse, mutect2, varscan2
- IGHV2-70 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs564009887; called by muse, mutect2, varscan2
- IGHV3-35 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.119); catalogued as rs772586386; called by muse, mutect2, varscan2
- IGLV4-60 | c.207G>A p.M69I | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs370708033; called by muse, mutect2, varscan2
- IRF5 | c.176G>A p.G59E | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.027); catalogued as COSV50857327; called by muse, mutect2
- IRF6 | c.1288G>A p.D430N | Missense Mutation (SNP) | VAF 99/573 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM022410; called by muse, mutect2, varscan2
- ITGA3 | c.2177C>T p.T726I | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.964); catalogued as COSV50320995; called by muse, mutect2, varscan2
- ITGAX | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV99191957; called by muse, mutect2, varscan2
- ITGAX | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.376); catalogued as rs1365549670; called by muse, mutect2, varscan2
- ITGB4 | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 71/316 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs754773105; called by muse, mutect2, varscan2
- ITLN1 | c.701G>A p.G234E | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs377155689; called by muse, mutect2, varscan2
- ITPKA | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.203); catalogued as COSV53029995; called by muse, mutect2
- ITPR3 | c.1147C>T p.R383W | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324375924; called by muse, mutect2
- ITPRIPL1 | c.329G>A p.G110E (on ENST00000439118 / NM_001008949.3; = p.G118E on NM_178495.6) | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV63154238; called by muse, varscan2
- JAKMIP2 | c.1402-1G>A p.X468_splice | Splice Site (SNP) | VAF 12/65 reads (18%) | catalogued as COSV54607339; called by muse, mutect2, varscan2
- KCNJ3 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.706); catalogued as COSV54531464; called by muse, mutect2
- KCP | c.3944C>T p.S1315L (on ENST00000620378; = p.S1439L on NM_001366122.1) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs1390709373; called by muse, mutect2, varscan2
- KDM4A | c.2261C>T p.P754L | Missense Mutation (SNP) | VAF 153/468 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as rs757318540, COSV64958765; called by muse, mutect2, varscan2
- KDM4B | c.3074C>T p.T1025I | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1387772117; called by muse, mutect2, varscan2
- KDM4D | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs781783527, COSV58635901; called by muse, mutect2, varscan2
- KDM5A | c.4634C>T p.S1545L | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1346692091; called by muse, mutect2, varscan2
- KEL | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 57/210 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV62335984; called by muse, mutect2, varscan2
- KHK | c.604C>T p.Q202* | Nonsense Mutation (SNP) | VAF 79/349 reads (23%) | catalogued as rs755659806; called by muse, mutect2, varscan2
- KIAA0319 | c.599G>A p.G200E | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.335); catalogued as rs769264904, COSV100985588; called by muse, mutect2, varscan2
- KIAA0319L | c.1010C>T p.P337L | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57848698; called by muse, mutect2, varscan2
- KLF17 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.103); catalogued as rs766222742, COSV64856058; called by muse, mutect2, varscan2
- KLHDC7A | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as rs749850924, COSV68769789; called by muse, mutect2, varscan2
- KLHL38 | c.1669G>A p.G557R | Missense Mutation (SNP) | VAF 32/211 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58087837; called by muse, mutect2, varscan2
- KRT9 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.389); catalogued as rs759302830, COSV55853235, COSV55855613; called by muse, mutect2, varscan2
- KRTAP22-1 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 62/267 reads (23%) | PolyPhen possibly damaging (0.69); catalogued as COSV58182200, COSV58182696; called by muse, varscan2
- L1TD1 | c.1427C>T p.S476F | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as rs1243672463; called by muse, mutect2, varscan2
- LCE6A | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.432); catalogued as rs1246023365; called by muse, mutect2
- LGMN | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs200318849, COSV58405135; called by muse, mutect2, varscan2
- LMO3 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.384); catalogued as COSV53783256, COSV99662475; called by muse, mutect2, varscan2
- LONP1 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 62/263 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as rs1325777808; called by muse, mutect2, varscan2
- LOXHD1 | c.3274C>T p.R1092C | Missense Mutation (SNP) | VAF 45/226 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs376791468, COSV56065943; called by muse, mutect2, varscan2
- LPA | c.2616G>A p.M872I | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.229); catalogued as COSV60309299; called by muse, mutect2, varscan2
- LRP1B | c.5291G>A p.G1764D | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1314265233, COSV67250756; called by muse, mutect2, varscan2
- LRP2 | c.11257A>G p.N3753D | Missense Mutation (SNP) | VAF 37/241 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.023); catalogued as rs766772739; called by muse, mutect2, varscan2
- LRP2 | c.5882C>T p.S1961F | Missense Mutation (SNP) | VAF 37/155 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV55547067; called by muse, mutect2, varscan2
- LRRIQ1 | c.3946G>A p.E1316K | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as COSV101280552; called by muse, mutect2, varscan2
- LRRTM3 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as COSV63666111; called by muse, mutect2, varscan2
- LRRTM4 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs200699710, COSV69139157, COSV69140155; called by muse, mutect2, varscan2
- LRTOMT | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.04); catalogued as rs146968362; called by muse, mutect2, varscan2
- LY75 | c.4484G>A p.G1495E | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV55101952; called by muse, mutect2, varscan2
- LY75 | c.514C>T p.P172S | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55113347; called by muse, mutect2, varscan2
- LY9 | c.737G>A p.G246E | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1317817313, COSV54436553; called by muse, mutect2, varscan2
- MAP3K9 | c.3278C>T p.P1093L (on ENST00000554752 / NM_001284230.1; = p.P1107L on NM_033141.4) | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs780374496, COSV67121377; called by muse, mutect2
- MAP4K4 | c.3505C>T p.R1169* (on ENST00000347699 / NM_001242559.2; = p.R1095* on NM_004834.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 44/172 reads (26%) | catalogued as rs1247832319, COSV56326034; called by muse, mutect2, varscan2
- MARCO | c.434G>A p.R145K | Missense Mutation (SNP) | VAF 23/158 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV100503811; called by muse, mutect2, varscan2
- MARVELD2 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs745719696; called by muse, mutect2, varscan2
- MAST4 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV101282552; called by muse, mutect2, varscan2
- MAST4 | c.4193C>T p.P1398L (on ENST00000403625 / NM_001164664.2; = p.P1209L on NM_015183.3) | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99846352; called by muse, mutect2, varscan2
- MCM10 | c.1064A>G p.N355S (on ENST00000484800 / NM_182751.3; = p.N354S on NM_018518.5) | Missense Mutation (SNP) | VAF 32/119 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776545237; called by muse, mutect2, varscan2
- MGAM2 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as rs4726491; called by muse, varscan2
- MME | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV64708634; called by muse, mutect2, varscan2
- MMP10 | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 29/156 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs771335701; called by muse, mutect2, varscan2
- MSI2 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.756); catalogued as rs1198633816; called by muse, mutect2, varscan2
- MSRA | c.543G>A p.K181= | Splice Region (SNP) | VAF 11/43 reads (26%) | catalogued as rs1443337129; called by muse, mutect2, varscan2
- MTOR | c.2942C>T p.S981F | Missense Mutation (SNP) | VAF 126/361 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100815632; called by muse, mutect2, varscan2
- MTTP | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 60/328 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs746203182, COSV55508172, COSV55510680; called by muse, mutect2, varscan2
- MTUS1 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs373001050; called by muse, mutect2, varscan2
- MUC16 | c.40880C>T p.P13627L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.985); catalogued as rs977298962, COSV66696472; called by muse, mutect2
- MUC16 | c.28349C>T p.S9450F | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.923); catalogued as rs770473024, COSV67463406; called by muse, mutect2, varscan2
- MUC16 | c.16451C>T p.S5484F | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.808); catalogued as COSV67491534; called by muse, mutect2, varscan2
- MUC3A | c.7913C>T p.T2638I | Missense Mutation (SNP) | VAF 35/234 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs561640605; called by muse, mutect2, varscan2
- MUC5B | c.11614G>A p.G3872S | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1232671071; called by muse, mutect2, varscan2
- MXRA5 | c.7747G>A p.D2583N | Missense Mutation (SNP) | VAF 60/209 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.24); catalogued as rs747665960, COSV54238737; called by muse, mutect2, varscan2
- MYBPC1 | c.125C>T p.P42L (on ENST00000550270 / NM_206820.2; = p.P67L on NM_002465.4) | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.164); catalogued as rs1421812200; called by muse, mutect2, varscan2
- MYBPC1 | c.2140C>T p.P714S (on ENST00000550270 / NM_206820.2; = p.P739S on NM_002465.4) | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62257795; called by muse, mutect2, varscan2
- MYF6 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs776595282; called by muse, mutect2, varscan2
- MYH1 | c.4380G>A p.W1460* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as rs1203438599, COSV56850091; called by muse, mutect2, varscan2
- MYH14 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371293576; called by muse, mutect2, varscan2
- MYH14 | c.4865G>A p.R1622Q | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs773412410; called by muse, mutect2, varscan2
- MYL1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV58975605; called by muse, mutect2, varscan2
- MYO3A | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56346333; called by muse, mutect2, varscan2
- MYOCD | c.835C>T p.P279S | Missense Mutation (SNP) | VAF 62/287 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58501714; called by muse, mutect2, varscan2
- MYRFL | c.1088A>G p.Q363R | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs974513903; called by muse, mutect2, varscan2
- NACAD | c.572G>A p.C191Y | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1049946703; called by muse, mutect2, varscan2
- NACC1 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); catalogued as rs1409088491; called by muse, mutect2, varscan2
- NBEA | c.4894C>T p.P1632S | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.968); catalogued as rs750159869; called by muse, mutect2, varscan2
- NEB | c.9188C>T p.S3063F | Missense Mutation (SNP) | VAF 32/243 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51428196; called by muse, varscan2
- NEIL2 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV52707035; called by muse, mutect2, varscan2
- NLRP8 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 20/113 reads (18%) | catalogued as COSV52582840; called by muse, mutect2, varscan2
- NOBOX | c.1210C>T p.P404S | Missense Mutation (SNP) | VAF 45/160 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs267601381; called by muse, mutect2, varscan2
- NOP53 | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 51/274 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs749617639; called by muse, mutect2, varscan2
- NOTCH2 | c.2288C>T p.S763L | Missense Mutation (SNP) | VAF 59/336 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs782306821, COSV56700266; called by muse, mutect2, varscan2
- NOTCH4 | c.2902G>A p.E968K | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV100900615; called by muse, varscan2
- NOXA1 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as rs1184802285; called by muse, mutect2, varscan2
- NPFFR2 | c.448T>A p.F150I | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as COSV58153579; called by muse, mutect2, varscan2
- NPRL2 | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 67/287 reads (23%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.744); catalogued as COSV51603612; called by muse, mutect2, varscan2
- NRXN3 | c.2159G>A p.G720E (on ENST00000335750 / NM_001330195.2; = p.G347E on NM_004796.6) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59732669; called by muse, mutect2, varscan2
- NYAP2 | c.1438G>A p.V480M | Missense Mutation (SNP) | VAF 42/165 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as rs760861891, COSV56012875; called by muse, mutect2, varscan2
- OR10AD1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.258); catalogued as COSV59613013; called by muse, mutect2, varscan2
- OR10H5 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV100454794, COSV58277876; called by muse, mutect2, varscan2
- OR10Z1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100778915, COSV63524906; called by muse, mutect2, varscan2
- OR14A16 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as COSV62926081; called by muse, mutect2, varscan2
- OR2L3 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as COSV63456503; called by muse, mutect2, varscan2
- OR4C11 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV56354253; called by muse, mutect2, varscan2
- OR4C12 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 33/137 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58859860; called by muse, mutect2, varscan2
- OR4K1 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs755426984, COSV53459544, COSV99579075; called by muse, mutect2, varscan2
- OR5AP2 | c.772T>C p.F258L | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100266014; called by muse, mutect2, varscan2
- OR5B12 | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.904); catalogued as COSV56904491; called by muse, mutect2, varscan2
- OR5B21 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs748770679, COSV64481991; called by muse, mutect2, varscan2
- OR5T1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV57302640; called by muse, mutect2
- OR6N2 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59411146; called by muse, mutect2, varscan2
- OR8B12 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV60911513; called by muse, mutect2, varscan2
- OR8B4 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.224); catalogued as COSV100635813; called by muse, mutect2, varscan2
- OR8I2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs867452723, COSV56166526; called by muse, mutect2
- PAGE2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 39/121 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV66596212; called by muse, mutect2, varscan2
- PAPPA | c.3831G>T p.Q1277H | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.844); catalogued as COSV60291598; called by muse, mutect2, varscan2
- PCARE | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 81/573 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs1279614167, COSV59053942; called by muse, mutect2, varscan2
- PCDH10 | c.2764G>A p.D922N | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV52088480; called by muse, mutect2, varscan2
- PCDH11X | c.3742C>T p.P1248S | Missense Mutation (SNP) | VAF 100/262 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as COSV100016706, COSV53467958; called by muse, mutect2, varscan2
- PCDH15 | c.5128C>T p.P1710S | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT tolerated, low confidence (0.14); catalogued as rs781357164, COSV100903462; called by muse, mutect2
- PCDHA10 | c.1089A>C p.Q363H | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV56522662; called by muse, mutect2, varscan2
- PCDHA12 | c.833C>T p.S278F | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.07); catalogued as COSV56480390; called by muse, mutect2, varscan2
- PCDHA7 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 48/198 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65343964; called by muse, mutect2, varscan2
- PCDHB11 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.723); catalogued as COSV61310289; called by muse, mutect2, varscan2
- PCDHGA4 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99527941; called by muse, mutect2, varscan2
- PCDHGB1 | c.2098C>T p.L700F | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.216); catalogued as rs764844897, COSV54051537; called by muse, mutect2, varscan2
- PCSK1 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as rs770310795, COSV60734749, COSV60737225; called by muse, varscan2
- PCSK1 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 66/314 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60733960; called by muse, varscan2
- PDE10A | c.2142G>A p.M714I | Missense Mutation (SNP) | VAF 34/176 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1469535794, COSV63092801; called by muse, mutect2, varscan2
- PDZD2 | c.4660G>A p.D1554N | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs746582090, COSV56855072; called by muse, mutect2, varscan2
- PES1 | c.902C>T p.P301L | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as COSV58828524; called by muse, mutect2, varscan2
- PFKFB2 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 25/213 reads (12%) | PolyPhen possibly damaging (0.563); catalogued as rs1343576153, COSV65547377; called by muse, mutect2, varscan2
- PIANP | c.828-5C>T | Splice Region (SNP) | VAF 12/77 reads (16%) | catalogued as rs1325543632; called by muse, mutect2, varscan2
- PKHD1 | c.7550C>T p.P2517L | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV61871276; called by muse, mutect2, varscan2
- PKHD1 | c.6935C>T p.S2312F | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1360592609; called by muse, mutect2, varscan2
- PLEKHD1 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV59446986; called by muse, mutect2, varscan2
- PLEKHG4B | c.632G>T p.R211L (on ENST00000283426; = p.R567L on NM_052909.5) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs769604175; called by muse, mutect2, varscan2
- PLXND1 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs1311254322; called by muse, mutect2, varscan2
- PNPLA5 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs776847523, COSV53374003; called by muse, mutect2, varscan2
- POLR3A | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV64931010; called by muse, mutect2, varscan2
- POM121 | c.832C>T p.P278S (on ENST00000434423; = p.P13S on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 224/671 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as rs533967943; called by muse, mutect2, varscan2
- PPARGC1A | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.294); catalogued as COSV53531063; called by muse, varscan2
- PPP1R15B | c.614C>T p.S205F | Missense Mutation (SNP) | VAF 143/524 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs754801130; called by muse, mutect2, varscan2
- PPP1R26 | c.2080G>A p.D694N | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63355735; called by muse, mutect2, varscan2
- PPP1R3A | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs1380388302, COSV52877979; called by muse, mutect2, varscan2
- PPP4R4 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100175851; called by muse, mutect2, varscan2
- PPT1 | c.383C>T p.P128L (on ENST00000433473; = p.P129L on NM_000310.4) | Missense Mutation (SNP) | VAF 123/524 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs758786265; called by muse, mutect2, varscan2
- PRAG1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.567); catalogued as rs1402743640, COSV58165040; called by muse, mutect2, varscan2
- PRAMEF15 | c.299G>A p.W100* | Nonsense Mutation (SNP) | VAF 31/168 reads (18%) | catalogued as rs1348434712; called by muse, varscan2
- PREX2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201372935, COSV99906079; called by muse, mutect2, varscan2
- PRIMA1 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs141491542, COSV60262625; called by muse, mutect2, varscan2
- PRKAG3 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.38); catalogued as COSV52103779; called by muse, mutect2, varscan2
- PRKG2 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.065); catalogued as rs867660938, COSV52320273; called by muse, mutect2
- PRPF38B | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 74/442 reads (17%) | catalogued as rs775081443, COSV100898294; called by muse, mutect2, varscan2
- PRSS38 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs1344792502; called by muse, mutect2
- PTGDR | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs942418183; called by muse, mutect2, varscan2
- PTGER2 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 31/159 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55418191; called by muse, mutect2, varscan2
- PTGS1 | c.1586C>T p.S529F | Missense Mutation (SNP) | VAF 45/132 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866722757, COSV56290280; called by muse, mutect2, varscan2
- PTPN22 | c.372C>T p.I124= | Splice Region (SNP) | VAF 34/134 reads (25%) | catalogued as COSV63084669; called by muse, varscan2
- PTPRC | c.2191G>A p.E731K | Missense Mutation (SNP) | VAF 39/242 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61416533; called by muse, mutect2, varscan2
- PTPRO | c.3128G>A p.R1043K (on ENST00000281171 / NM_030667.3; = p.R1015K on NM_002848.4) | Missense Mutation (SNP) | VAF 57/327 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.944); catalogued as rs749489011, COSV55510662; called by muse, mutect2, varscan2
- RALGAPA1 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.846); catalogued as rs144800983; called by muse, mutect2
- RASA1 | c.2225C>G p.S742* | Nonsense Mutation (SNP) | VAF 21/269 reads (8%) | catalogued as CM121692, COSV57196988; called by muse, mutect2
- RASGEF1B | c.1045C>T p.R349* | Nonsense Mutation (SNP) | VAF 21/187 reads (11%) | catalogued as rs766671987, COSV52339448; called by muse, mutect2, varscan2
- RASIP1 | c.2629C>T p.P877S | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.979); catalogued as COSV55809010; called by muse, mutect2, varscan2
- RD3 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.381); catalogued as rs1157836749; called by muse, mutect2, varscan2
- RIMS1 | c.2765C>T p.P922L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1394636164, COSV53462666; called by muse, mutect2, varscan2
- RNASE9 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 38/207 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs1052356881; called by muse, mutect2, varscan2
- RNF115 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV65164119; called by muse, mutect2, varscan2
- RNF149 | c.920C>T p.P307L | Missense Mutation (SNP) | VAF 44/288 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54863432, COSV99766617; called by muse, mutect2, varscan2
- RNF183 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.234); catalogued as COSV52908013; called by muse, mutect2, varscan2
- RNF38 | c.573C>T p.L191= | Splice Region (SNP) | VAF 23/95 reads (24%) | catalogued as COSV52392708; called by muse, mutect2, varscan2
- RP1 | c.2366C>T p.S789F | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.614); catalogued as rs750057815; called by muse, mutect2, varscan2
- RPE65 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 38/241 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52016102; called by muse, mutect2, varscan2
- RPGRIP1 | c.3058G>C p.E1020Q | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV52843800; called by muse, mutect2, varscan2
- RPL5 | c.212G>A p.G71E | Missense Mutation (SNP) | VAF 120/428 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV59873502; called by muse, mutect2, varscan2
- RTKN2 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 22/342 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs191159688, COSV59523672; called by muse, mutect2
- RYR2 | c.4891C>T p.H1631Y | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.084); catalogued as rs786205423; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.10483C>T p.R3495* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV63692243; called by mutect2, varscan2
- RYR2 | c.12112G>A p.D4038N | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.93); catalogued as rs1254415608, COSV63698671; called by muse, varscan2
- RYR2 | c.12265G>A p.E4089K | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV63666618; called by muse, varscan2
- RYR3 | c.2938G>A p.E980K | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.177); catalogued as COSV101212440; called by muse, mutect2, varscan2
- SALL4 | c.3017C>T p.S1006F | Missense Mutation (SNP) | VAF 63/268 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV53850386; called by muse, mutect2, varscan2
- SCNN1D | c.127G>A p.E43K (on ENST00000338555; = p.E207K on NM_001130413.4) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs1164023414; called by muse, mutect2
- SELL | c.289C>T p.R97C (on ENST00000650983; = p.R84C on NM_000655.5) | Missense Mutation (SNP) | VAF 64/316 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs752812666; called by muse, mutect2, varscan2
- SEMA4D | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as COSV59399294; called by muse, mutect2, varscan2
- SEMA6B | c.1927G>A p.G643R | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.92); catalogued as rs1033085752; called by muse, mutect2
- SENP3 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs1358768792; called by muse, mutect2, varscan2
- SERPINA10 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 39/193 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as rs267604109, COSV56228009; called by muse, mutect2, varscan2
- SERPINA7 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs148370308, COSV59666422; called by muse, mutect2, varscan2
- SERPINB11 | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as rs746042954; called by mutect2, varscan2
- SERPINI1 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV55507755; called by muse, mutect2, varscan2
- SHANK2 | c.5288C>T p.S1763L | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53606732; called by muse, mutect2, varscan2
- SHBG | c.852+7G>A | Splice Region (SNP) | VAF 57/256 reads (22%) | catalogued as rs377736382; called by muse, varscan2
- SHISA3 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.147); catalogued as COSV59979380; called by muse, mutect2
- SHISA3 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as COSV59980655; called by muse, mutect2, varscan2
- SIM1 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.364); catalogued as COSV53491433; called by muse, mutect2, varscan2
- SIRPG | c.229A>T p.I77F | Missense Mutation (SNP) | VAF 64/298 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53809175; called by muse, mutect2
- SLC12A1 | c.1954G>A p.G652S | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM108771; called by muse, mutect2, varscan2
- SLC12A3 | c.433C>T p.R145C | Missense Mutation (SNP) | VAF 78/500 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148945966, CM075012, COSV99344049; called by muse, varscan2
- SLC13A1 | c.256C>T p.H86Y | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52011443; called by muse, mutect2, varscan2
- SLC14A2 | c.1709G>A p.G570E | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV54907572; called by muse, mutect2, varscan2
- SLC23A3 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.242); catalogued as rs541491009; called by muse, mutect2, varscan2
- SLC27A5 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770786072; called by muse, mutect2, varscan2
- SLC30A4 | c.1136-2A>T p.X379_splice | Splice Site (SNP) | VAF 11/39 reads (28%) | catalogued as COSV99970081; called by muse, mutect2, varscan2
- SLC44A4 | c.462G>A p.W154* | Nonsense Mutation (SNP) | VAF 5/48 reads (10%) | catalogued as COSV57667043; called by muse, mutect2
- SLC4A5 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV100697438; called by muse, mutect2, varscan2
- SLC6A11 | c.1814G>A p.R605Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs755297702; called by muse, mutect2, varscan2
- SLC6A9 | c.967C>T p.P323S (on ENST00000360584 / NM_201649.4; = p.P269S on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62211630; called by muse, mutect2, varscan2
- SLC7A10 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 59/285 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1484553024, COSV53504845; called by muse, mutect2, varscan2
- SLCO1B3 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53938416; called by muse, mutect2, varscan2
- SLCO5A1 | c.1609C>T p.P537S | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV52653980; called by muse, mutect2, varscan2
- SLFN5 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 36/259 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs748504235; called by muse, mutect2, varscan2
- SLITRK1 | c.2012C>T p.S671F | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.147); catalogued as COSV65677743; called by muse, mutect2, varscan2
- SNAP91 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.364); catalogued as COSV52116649; called by muse, mutect2, varscan2
- SNTG1 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as rs764804995, COSV52440797; called by muse, mutect2, varscan2
- SOGA3 | c.2818C>T p.L940F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1562377274; called by muse, mutect2, varscan2
- SOGA3 | c.2095G>A p.E699K | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.37); catalogued as COSV100846857; called by muse, mutect2, varscan2
- SON | c.5600C>T p.S1867L | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.868); catalogued as COSV99277173; called by muse, mutect2, varscan2
- SPACA3 | c.613G>A p.D205N | Missense Mutation (SNP) | VAF 40/213 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); catalogued as COSV52190248, COSV52191767; called by muse, mutect2, varscan2
- SPAG17 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV60469368; called by muse, mutect2
- SPAM1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs867782585; called by muse, mutect2, varscan2
- SPATA31A6 | c.1568C>A p.A523E | Missense Mutation (SNP) | VAF 56/271 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as rs570868586; called by muse, mutect2, varscan2
- SPEF2 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.454); catalogued as COSV61552175; called by muse, mutect2
- SPHKAP | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1416078052, COSV100763912; called by muse, mutect2, varscan2
- SPHKAP | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV60869794; called by muse, mutect2, varscan2
- SPHKAP | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.368); catalogued as COSV60875071; called by muse, mutect2, varscan2
- SPINK5 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 98/590 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs775297343; called by muse, mutect2, varscan2
- SPTLC3 | c.82A>C p.N28H | Missense Mutation (SNP) | VAF 38/301 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs1269316878; called by muse, mutect2, varscan2
- SREBF2 | c.2066C>T p.S689F | Missense Mutation (SNP) | VAF 125/535 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.084); catalogued as rs747355316, COSV99072308; called by muse, mutect2, varscan2
- STK32A | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs758734263, COSV60416210; called by muse, mutect2, varscan2
- STRN4 | c.253C>T p.R85C | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1253420541; called by muse, mutect2, varscan2
- STX17 | c.35G>C p.R12P | Missense Mutation (SNP) | VAF 39/208 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV52283062; called by muse, mutect2, varscan2
- SUCO | c.3142C>T p.P1048S | Missense Mutation (SNP) | VAF 24/161 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as COSV55271648; called by muse, mutect2, varscan2
- SULT1E1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs771777989; called by muse, mutect2, varscan2
- SULT2A1 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as rs370526585; called by muse, mutect2, varscan2
- SYCE1 | c.352G>A p.E118K (on ENST00000343131 / NM_001143764.3; = p.E82K on NM_130784.3) | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.442); catalogued as COSV58219554; called by muse, mutect2
- SYCP2L | c.2290C>T p.L764F | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1029639738, COSV51652368; called by muse, mutect2, varscan2
- SYK | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs200438123, COSV65325080, COSV65328872; called by muse, mutect2, varscan2
- SYMPK | c.3676C>T p.P1226S | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs781586274; called by muse, mutect2, varscan2
- TAF1L | c.1934G>A p.G645D | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs375468213; called by muse, mutect2, varscan2
- TAMM41 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as rs1260420737; called by muse, mutect2, varscan2
- TBC1D22B | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 76/315 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as COSV65143772; called by muse, mutect2, varscan2
- TBC1D8B | c.1768G>A p.E590K | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV52176933; called by muse, mutect2, varscan2
- TBX15 | c.1643C>T p.S548F (on ENST00000369429 / NM_001330677.2; = p.S442F on NM_152380.3) | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.276); catalogued as rs776777911; called by muse, mutect2, varscan2
- TBX5 | c.1469C>T p.S490F | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.204); catalogued as COSV59858392, COSV59861141; called by muse, mutect2, varscan2
- TDRD5 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV54241044; called by muse, mutect2, varscan2
- TECTA | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs915704164; called by muse, mutect2, varscan2
- TEX14 | c.3821C>T p.S1274F (on ENST00000240361 / NM_001201457.2; = p.S1228F on NM_031272.5) | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as rs1297775713, COSV53620820; called by muse, mutect2, varscan2
- TEX14 | c.1087G>T p.A363S (on ENST00000240361 / NM_001201457.2; = p.A357S on NM_031272.5) | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759758492, COSV53623063; called by muse, mutect2, varscan2
- TEX15 | c.1103G>A p.G368E (on ENST00000256246; = p.G751E on NM_001350162.2) | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99820982; called by muse, mutect2, varscan2
- TEX2 | c.1026C>A p.N342K | Missense Mutation (SNP) | VAF 81/394 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as rs1349687794; called by muse, mutect2, varscan2
- TFAP2D | c.67C>T p.R23C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1455239820, COSV50431210, COSV99145856; called by muse, varscan2
- TGM7 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 35/251 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV71773093; called by muse, mutect2, varscan2
- TMCO5A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.996); catalogued as rs756633826, COSV60464273; called by muse, mutect2, varscan2
- TMEM132B | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV54773291; called by muse, mutect2, varscan2
- TMPO | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); catalogued as rs138938727, COSV54123117, COSV54125209; called by muse, mutect2, varscan2
- TNFRSF13B | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs1206383760; called by muse, mutect2, varscan2
- TNR | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs372172451; called by muse, mutect2, varscan2
- TRAV6 | c.320C>T p.T107I | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as rs1320382738; called by muse, mutect2, varscan2
- TRBV5-1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs1410149225; called by muse, mutect2, varscan2
- TRERF1 | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs1339040830; called by muse, mutect2, varscan2
- TSPO2 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs756823502, COSV55109906; called by muse, mutect2, varscan2
- TTC3 | c.1639C>T p.L547F | Missense Mutation (SNP) | VAF 54/262 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1039835777; called by muse, mutect2, varscan2
- TTN | c.68807C>T p.S22936F (on ENST00000591111; = p.S15512F on NM_003319.4) | Missense Mutation (SNP) | VAF 21/84 reads (25%) | PolyPhen possibly damaging (0.664); catalogued as COSV59998498; called by muse, mutect2, varscan2
- TTN | c.39521G>A p.G13174E (on ENST00000591111; = p.G5750E on NM_003319.4) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | PolyPhen probably damaging (0.959); catalogued as rs1157011423, COSV60041104, COSV60280736; called by muse, mutect2, varscan2
- TTN | c.39074G>A p.G13025E (on ENST00000591111; = p.G5601E on NM_003319.4) | Missense Mutation (SNP) | VAF 64/287 reads (22%) | PolyPhen benign (0.146); catalogued as COSV59903684; called by muse, mutect2, varscan2
- TTN | c.17761G>A p.E5921K (on ENST00000591111; = p.E4994K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/169 reads (21%) | PolyPhen possibly damaging (0.819); catalogued as COSV59996401; called by muse, mutect2, varscan2
- TTN | c.14456C>T p.S4819L (on ENST00000591111; = p.S3892L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/95 reads (21%) | PolyPhen possibly damaging (0.452); catalogued as rs764310312, COSV59969202; called by muse, mutect2, varscan2
- TTN | c.5942G>C p.R1981T (on ENST00000591111; = p.R1935T on NM_003319.4) | Missense Mutation (SNP) | VAF 82/378 reads (22%) | PolyPhen benign (0.382); catalogued as COSV100608881; called by muse, mutect2, varscan2
- TTN | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 98/444 reads (22%) | PolyPhen benign (0.221); catalogued as COSV59918010; called by muse, mutect2, varscan2
- U2AF2 | c.166C>T p.R56W | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as rs1216613172; called by muse, mutect2, varscan2
- UBN2 | c.3808C>T p.P1270S | Missense Mutation (SNP) | VAF 176/558 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV56027458; called by muse, mutect2, varscan2
- UBR4 | c.12353C>T p.P4118L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs768724983; called by muse, mutect2, varscan2
- UGT1A7 | c.200G>A p.G67E | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as rs1381446739; called by muse, mutect2, varscan2
- UNC13A | c.531G>A p.W177* | Nonsense Mutation (SNP) | VAF 27/162 reads (17%) | catalogued as COSV53213520; called by muse, mutect2, varscan2
- UNC13C | c.1942C>T p.L648F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.117); catalogued as COSV99524926; called by muse, mutect2, varscan2
- UNC79 | c.1486G>A p.D496N (on ENST00000393151 / NM_001346218.2; = p.D319N on NM_020818.5) | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs748303152, COSV56375212; called by muse, mutect2, varscan2
- USP47 | c.485C>T p.S162F (on ENST00000399455 / NM_001372095.1; = p.S74F on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/152 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.275); catalogued as COSV60463487; called by muse, mutect2, varscan2
- USP6 | c.3434C>T p.A1145V | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.014); catalogued as rs761969513; called by muse, mutect2, varscan2
- VAT1L | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 82/298 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.905); catalogued as rs1419393520; called by muse, mutect2, varscan2
- VEPH1 | c.2402C>T p.A801V | Missense Mutation (SNP) | VAF 61/271 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100747864; called by muse, mutect2, varscan2
- VPS13D | c.10064C>T p.S3355F | Missense Mutation (SNP) | VAF 114/375 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs769322835; called by muse, mutect2, varscan2
- VSTM2B | c.668C>A p.A223E | Missense Mutation (SNP) | VAF 22/182 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs986044670; called by muse, mutect2, varscan2
- WDR7 | c.4310C>T p.S1437L | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs771983661, COSV54364034; called by muse, mutect2, varscan2
- WNT4 | c.208G>A p.G70S | Missense Mutation (SNP) | VAF 170/547 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs371203462; called by mutect2, varscan2
- WRAP53 | c.1043C>T p.S348F | Missense Mutation (SNP) | VAF 55/242 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as rs1258025228; called by muse, mutect2, varscan2
- XKR4 | c.1766G>A p.R589Q | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as rs1392195420, COSV59340976; called by muse, mutect2, varscan2
- XKRX | c.623C>T p.S208F | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV60707812; called by muse, mutect2, varscan2
- ZAN | c.1949C>T p.S650F | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV61805735, COSV61809213; called by muse, mutect2, varscan2
- ZBTB33 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs781878176; called by muse, mutect2, varscan2
- ZDHHC11B | c.953C>T p.S318F | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.496); catalogued as rs778525352; called by muse, mutect2, varscan2
- ZIC4 | c.503A>T p.Q168L | Missense Mutation (SNP) | VAF 133/360 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs376055510; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2707C>T p.R903* | Nonsense Mutation (SNP) | VAF 19/58 reads (33%) | catalogued as rs932733214, COSV60155488; called by muse, mutect2, varscan2
- ZMYM6 | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV100593119; called by muse, mutect2, varscan2
- ZNF366 | c.2017G>A p.G673R | Missense Mutation (SNP) | VAF 96/459 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV59217574; called by muse, mutect2, varscan2
- ZNF404 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); catalogued as rs200263609; called by muse, mutect2, varscan2
- ZNF417 | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV56307351; called by muse, mutect2, varscan2
- ZNF425 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 87/269 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs758029795; called by muse, mutect2, varscan2
- ZNF473 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 56/189 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV54524772; called by muse, mutect2, varscan2
- ZNF497 | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.356); catalogued as rs777179698; called by muse, mutect2, varscan2
- ZNF503 | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs754179443; called by muse, mutect2
- ZNF583 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.607); catalogued as rs770179377, COSV52403202; called by muse, mutect2, varscan2
- ZNF804A | c.2380G>A p.E794K | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.588); catalogued as COSV56435127, COSV56470008; called by muse, mutect2, varscan2
- ZNF804A | c.2737G>A p.D913N | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV56448503, COSV56464562; called by muse, mutect2, varscan2
- ZNF827 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as rs749278908; called by muse, mutect2, varscan2
- ZNF827 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1489287595; called by muse, mutect2, varscan2
- ZNF844 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV71518593; called by muse, mutect2, varscan2
- ZP2 | c.484-3C>T | Splice Region (SNP) | VAF 45/249 reads (18%) | catalogued as rs1055206280; called by muse, mutect2, varscan2
- ZSWIM2 | c.749C>T p.T250I | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.335); catalogued as COSV54574232, COSV54579212; called by muse, mutect2
- AATK | c.2705C>T p.S902F (on ENST00000326724 / NM_001080395.3; = p.S799F on NM_004920.2) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- ABCA4 | c.6556G>A p.E2186K | Missense Mutation (SNP) | VAF 56/393 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ABCC2 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 92/309 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC011462.1 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AC132807.2 | n.10G>A | Splice Region (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- ACOT9 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 63/131 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ACOT9 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- ACSF2 | c.541T>G p.F181V | Missense Mutation (SNP) | VAF 52/257 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADAM18 | c.805del p.H269Mfs*3 | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | called by mutect2, pindel, varscan2
- ADAM23 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADAMTS14 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.42); called by muse, mutect2
- ADAMTS14 | c.3638G>A p.G1213D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); called by mutect2, varscan2
- ADAMTS7 | c.3149C>T p.P1050L | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCK1 | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- ADGRV1 | c.3313G>A p.G1105R | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- ADGRV1 | c.9328G>A p.G3110R | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADPRHL1 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); called by muse, varscan2
- AFM | c.1715A>T p.N572I | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- AHNAK | c.16280C>T p.P5427L | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHNAK | c.16279C>T p.P5427S | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AJAP1 | c.860C>T p.T287I | Missense Mutation (SNP) | VAF 68/292 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKAP6 | c.3578G>A p.G1193E | Missense Mutation (SNP) | VAF 69/283 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- AKAP6 | c.4379G>A p.G1460E | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- AL163195.3 | c.131+1G>A p.X44_splice | Splice Site (SNP) | VAF 49/203 reads (24%) | called by muse, mutect2, varscan2
- AL592490.1 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- AL645922.1 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 49/363 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- ALMS1 | c.4001A>T p.Y1334F | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, varscan2
- ALPK2 | c.1153T>A p.S385T | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMBRA1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMER3 | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ANK3 | c.10411G>A p.G3471R | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANK3 | c.2711G>A p.G904D (on ENST00000280772 / NM_001320874.2; = p.G38D on NM_001149.3) | Missense Mutation (SNP) | VAF 15/327 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD31 | c.3877C>T p.P1293S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ANKRD31 | c.1834C>T p.Q612* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | called by muse, mutect2, varscan2
- ANKRD34C | c.677T>A p.V226D | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- AOC3 | c.1432G>A p.V478I | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- APBB1IP | c.1124A>T p.K375I | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- APC2 | c.1621G>T p.V541F | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- APOA2 | c.-24-5C>T | Splice Region (SNP) | VAF 28/254 reads (11%) | called by muse, mutect2, varscan2
- APOF | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 85/522 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARAF | c.635C>T p.S212F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- ARAP2 | c.4618G>A p.D1540N | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2
- ARAP2 | c.2328A>C p.E776D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ARAP2 | c.293C>T p.S98F | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP23 | c.4418C>T p.S1473F | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARHGAP5 | c.4132C>T p.H1378Y (on ENST00000345122 / NM_001030055.2; = p.H1377Y on NM_001173.3) | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- ARID3C | c.1016G>T p.S339I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); called by muse, varscan2
- ASAP3 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 74/232 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASTN2 | c.1661G>A p.W554* (on ENST00000313400 / NM_001365069.1; = p.W503* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | called by muse, mutect2
- ASXL2 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 50/276 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- ATP5F1B | c.1529_1531del p.V510del | In Frame Del (DEL) | VAF 58/398 reads (15%) | called by pindel, varscan2
- ATXN1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 39/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- BCAS1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); called by muse, mutect2
- BDP1 | c.2096T>C p.L699S | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BIN3 | c.558del p.Y187Tfs*91 | Frame Shift Del (DEL) | VAF 39/231 reads (17%) | called by mutect2, pindel, varscan2
- BMT2 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 127/349 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BOLL | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, varscan2
- BPIFB1 | c.982-2A>C p.X328_splice | Splice Site (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2
- BPIFB6 | c.1189-1G>A p.X397_splice | Splice Site (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- BPIFB6 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- BPTF | c.4676G>A p.S1559N | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BTN1A1 | c.885G>A p.W295* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- C11orf49 | c.366-7C>T | Splice Region (SNP) | VAF 26/154 reads (17%) | called by muse, mutect2, varscan2
- C12orf40 | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 47/239 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- C1orf185 | c.355C>T p.P119S | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- C20orf173 | c.346G>A p.G116S (on ENST00000246199; = p.G169S on NM_001145350.2) | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- C2CD6 | c.382C>A p.H128N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.45); called by muse, mutect2
- C2orf16 | c.667C>T p.Q223* | Nonsense Mutation (SNP) | VAF 35/171 reads (20%) | called by muse, mutect2, varscan2
- C2orf81 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- C2orf81 | c.1243C>G p.P415A | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- C6orf132 | c.3547C>T p.H1183Y | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- CABS1 | c.636T>G p.I212M | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CACNA2D2 | c.2422+1G>A p.X808_splice (on ENST00000479441 / NM_001174051.3; = p.X801_splice on NM_006030.4) | Splice Site (SNP) | VAF 40/159 reads (25%) | called by muse, mutect2, varscan2
- CALCOCO1 | c.1084C>T p.L362F | Missense Mutation (SNP) | VAF 91/423 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CAPRIN2 | c.2321A>T p.N774I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2
- CASKIN1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- CBLC | c.766G>A p.D256N | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- CBLN4 | c.160G>A p.G54S | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CD22 | c.2249G>A p.G750E | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CD27 | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 38/213 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD300A | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- CDCA7L | c.25-1G>A p.X9_splice | Splice Site (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- CDH3 | c.406G>A p.D136N | Missense Mutation (SNP) | VAF 45/304 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- CELSR3 | c.9052C>T p.P3018S | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP170 | c.4414-8C>T | Splice Region (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- CES4A | c.736C>T p.Q246* | Nonsense Mutation (SNP) | VAF 95/360 reads (26%) | called by muse, mutect2, varscan2
- CFAP46 | c.3134T>G p.L1045R | Missense Mutation (SNP) | VAF 29/146 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CFAP53 | c.918A>T p.E306D | Missense Mutation (SNP) | VAF 67/283 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CFAP92 | c.2268G>T p.R756S | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.242); called by muse, varscan2
- CFAP92 | c.1472G>A p.G491E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CFTR | c.4420G>A p.E1474K | Missense Mutation (SNP) | VAF 193/583 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- CGB7 | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- CHD8 | c.2744C>T p.P915L (on ENST00000646647 / NM_001170629.2; = p.P636L on NM_020920.4) | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.18); called by muse, mutect2
- CHST5 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLDN17 | c.440A>T p.D147V | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CLEC17A | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 29/214 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLEC18B | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.326); called by muse, mutect2
- CMYA5 | c.4373C>T p.S1458F | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CNTN2 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 44/234 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- COL1A1 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2
- COL2A1 | c.383C>A p.A128E | Missense Mutation (SNP) | VAF 41/476 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.025); called by muse, mutect2
- COL4A3 | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 35/166 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL4A4 | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 33/162 reads (20%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- COL4A4 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 57/295 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A6 | c.6293G>A p.G2098E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- COL7A1 | c.6086C>G p.P2029R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- COL7A1 | c.5363G>A p.G1788E | Missense Mutation (SNP) | VAF 49/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL9A2 | c.1662G>A p.M554I | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CP | c.1873G>A p.G625R | Missense Mutation (SNP) | VAF 70/261 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPAMD8 | c.3152G>A p.G1051E (on ENST00000651564; = p.G1004E on NM_015692.5) | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD1 | c.3355C>T p.P1119S (on ENST00000520002; = p.P1118S on NM_033225.6) | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CWF19L2 | c.813T>G p.D271E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CYP7A1 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- DCAF13 | c.988T>G p.C330G | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- DCC | c.2475T>A p.D825E | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DCLRE1B | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DDB1 | c.1807C>T p.L603F | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- DENND2A | c.2116C>T p.P706S | Missense Mutation (SNP) | VAF 57/178 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- DGKB | c.1973G>A p.G658E | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIDO1 | c.3676C>T p.P1226S | Missense Mutation (SNP) | VAF 83/326 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMXL1 | c.6859C>T p.P2287S | Missense Mutation (SNP) | VAF 42/207 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- DNAH11 | c.3791G>A p.R1264K | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DNAH14 | c.3617T>A p.L1206Q | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH8 | c.7006G>A p.E2336K | Missense Mutation (SNP) | VAF 48/207 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- DNAH8 | c.7862T>A p.F2621Y | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH9 | c.5143C>T p.P1715S | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- DNALI1 | c.634G>A p.E212K (on ENST00000296218; = p.E190K on NM_003462.5) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- DOCK8 | c.4025G>A p.G1342E | Missense Mutation (SNP) | VAF 42/170 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- DPEP2 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- DPP3 | c.2143C>T p.L715F | Missense Mutation (SNP) | VAF 64/343 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- DSC1 | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, varscan2
- DSC3 | c.1783T>G p.L595V | Missense Mutation (SNP) | VAF 68/354 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSCAM | c.3527G>A p.R1176K | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); called by muse, varscan2
- DST | c.10612G>A p.D3538N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DST | c.8362T>G p.C2788G | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- DST | c.473T>C p.L158P | Missense Mutation (SNP) | VAF 50/250 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYNC2H1 | c.5950G>A p.G1984R | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC2H1 | c.11675C>T p.S3892F | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DYNC2LI1 | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- E4F1 | c.2023G>A p.V675M | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ECM2 | c.1457C>T p.S486F | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EDNRA | c.933G>C p.L311F | Missense Mutation (SNP) | VAF 21/175 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EFCAB6 | c.882+7T>G | Splice Region (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- ELOVL2 | c.489G>A p.W163* | Nonsense Mutation (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- ENPP6 | c.169G>A p.G57R | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ENTHD1 | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ENTPD6 | c.761G>A p.G254E | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L1 | c.1863C>A p.D621E | Missense Mutation (SNP) | VAF 67/378 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- EPG5 | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESYT3 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EYS | c.6068G>A p.G2023E | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- F5 | c.5983G>A p.V1995I | Missense Mutation (SNP) | VAF 48/258 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- FA2H | c.1082C>T p.T361I | Missense Mutation (SNP) | VAF 46/221 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM120A | c.2572C>T p.P858S | Missense Mutation (SNP) | VAF 70/338 reads (21%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- FAM135B | c.1691C>T p.S564F | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM177B | c.436G>A p.G146R | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM184B | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- FAM186A | c.1732G>A p.G578S | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM47C | c.1885C>T p.H629Y | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.877); called by muse, varscan2
- FBXO38 | c.3024_3024+15del p.X1008_splice (on ENST00000340253 / NM_205836.3; = p.X933_splice on NM_030793.5) | Splice Site (DEL) | VAF 22/95 reads (23%) | called by mutect2, pindel
- FCRL3 | c.2040G>A p.M680I | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGA | c.1640G>A p.R547K | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FGB | c.1263A>T p.R421S | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.78); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FGFR2 | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2
- FHOD3 | c.2182G>A p.D728N (on ENST00000359247 / NM_001281739.3; = p.D745N on NM_025135.5) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.226); called by muse, mutect2
- FLG | c.2627C>T p.S876F | Missense Mutation (SNP) | VAF 90/444 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, varscan2
- FLNB | c.3214G>A p.G1072S | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2
- FMR1NB | c.622T>A p.F208I | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- FOLH1B | n.804A>T | Splice Region (SNP) | VAF 33/92 reads (36%) | called by muse, mutect2, varscan2
- FOXA2 | c.349G>A p.A117T (on ENST00000377115 / NM_153675.3; = p.A123T on NM_021784.5) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- FREM2 | c.8783C>T p.P2928L | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FSIP2 | c.6868G>A p.E2290K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- FZD1 | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- GABRR3 | c.482A>T p.N161I | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GAREM1 | c.1214G>A p.G405D | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GDPGP1 | c.871G>T p.V291F | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- GFY | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 80/322 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GJA10 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GJB5 | c.131G>A p.W44* | Nonsense Mutation (SNP) | VAF 71/293 reads (24%) | called by muse, mutect2, varscan2
- GLRA3 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, varscan2
- GLRB | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- GLTP | c.29A>G p.K10R | Missense Mutation (SNP) | VAF 50/312 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLYATL2 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.006); called by muse, varscan2
- GOLGA6L6 | c.2005G>A p.E669K | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GPHN | c.1538C>T p.P513L (on ENST00000315266 / NM_001377519.1; = p.P546L on NM_020806.5) | Missense Mutation (SNP) | VAF 63/340 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- GPNMB | c.388C>T p.P130S | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.73); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPR179 | c.866G>T p.W289L (on ENST00000621958; = p.W288L on NM_001004334.4) | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPRC6A | c.593C>A p.A198E | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRB2 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 124/434 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GRIK2 | c.1239G>A p.M413I | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIN2A | c.1625G>A p.G542D | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GRM7 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 38/190 reads (20%) | called by muse, mutect2, varscan2
- GTDC1 | c.1006A>G p.K336E | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GUCY1B1 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY2C | c.355C>T p.L119F | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.63); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- GUCY2F | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.77); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- H1-7 | c.545C>G p.A182G | Missense Mutation (SNP) | VAF 48/259 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- HAPLN1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HAPLN3 | c.377_378del p.E126Afs*2 | Frame Shift Del (DEL) | VAF 36/247 reads (15%) | called by pindel, varscan2
- HCRT | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HECW1 | c.2528G>A p.G843E | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.581G>A p.R194K | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- HLA-DMB | c.174G>T p.E58D | Missense Mutation (SNP) | VAF 60/305 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- HMGA2 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 103/518 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HPSE2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- IGFN1 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHD | c.176G>A p.R59K | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHV1-46 | c.310A>C p.S104R | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IGHV1-46 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 50/339 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- IGHV1-46 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- IGLV1-47 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- IGSF10 | c.3203C>T p.P1068L | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- IL18RAP | c.1195G>A p.D399N | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- IL19 | c.473G>A p.G158E | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSM1 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ITFG2 | c.783C>G p.N261K | Missense Mutation (SNP) | VAF 35/193 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ITGA4 | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ITGBL1 | c.382del p.Y128Tfs*7 | Frame Shift Del (DEL) | VAF 49/196 reads (25%) | called by mutect2, pindel, varscan2
- ITIH1 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 81/302 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- ITPR2 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 91/335 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR3 | c.1146C>T p.P382= | Splice Region (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2
- ITPRID1 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.029); called by muse, mutect2, varscan2
992 further variants in this file (280 protein-altering or splice-affecting, 466 silent, 246 other) are not listed here.
